Somatic mutation profile of tumor specimen MMRF_2685_1_BM_CD138pos (aliquot MMRF_2685_1_BM_CD138pos_T1_KHS5U_L14255) from MMRF case MMRF_2685, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.6 years (23,213 days).
Specimen MMRF_2685_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba1f6ab4-3d7c-4e87-af4f-0d8f15d76875.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2685_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2685_1_PB_WBC_C2_KHS5U_L14256; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f53c47ae-4fd6-4e46-8426-a07efe1aa970

The open-access MAF lists 120 somatic variants for this specimen: 50 protein-altering or splice-affecting, 17 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 24, Silent 17, Intron 14, 3'Flank 5, RNA 4, 5'UTR 3, 5'Flank 3, Frame Shift Del 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 19/344 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADGRF4 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1043458840, COSV51957230; called by muse, mutect2, varscan2
- ANKS4B | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs755676619; called by muse, mutect2, varscan2
- ATP10B | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as rs1196903728; called by muse, mutect2, varscan2
- BRCA2 | c.5512G>A p.E1838K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.978); catalogued as COSV66450389; called by muse, mutect2, varscan2
- C5orf46 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 128/335 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs755537448; called by muse, mutect2, varscan2
- CFAP52 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs150503527, COSV55345796; called by muse, mutect2, varscan2
- CYP4F12 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs369172315; called by muse, mutect2, varscan2
- FBLN1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549459139; called by muse, mutect2, varscan2
- FMN1 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT tolerated, low confidence (0.43); catalogued as rs745819682; called by muse, mutect2, varscan2
- GLI2 | c.3675C>A p.S1225R (on ENST00000361492 / NM_001374353.1; = p.S1242R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); catalogued as rs775121883; called by muse, mutect2, varscan2
- GPR149 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as COSV67665705; called by muse, mutect2, varscan2
- HTATIP2 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs772920011; called by muse, varscan2
- IGHV2-70 | c.127T>G p.F43V | Missense Mutation (SNP) | VAF 70/88 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs374779982; called by muse, varscan2
- IGLV7-46 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs552451226; called by muse, mutect2, varscan2
- MUC4 | c.15991C>T p.H5331Y (on ENST00000463781 / NM_018406.7; = p.H1095Y on NM_004532.6) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as rs765942078, COSV57777484; called by muse, mutect2
- OR10G7 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs750311471, COSV100389702; called by muse, mutect2, varscan2
- SETDB1 | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 153/520 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54990089; called by muse, mutect2, varscan2
- SMARCA1 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886080461, COSV64412631; called by muse, mutect2, varscan2
- STC2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 276/625 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs758725089, COSV54178800; called by muse, mutect2, varscan2
- TRIM15 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.517); catalogued as rs939685910; called by muse, mutect2, varscan2
- UNC5D | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 89/142 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54795571; called by muse, mutect2, varscan2
- AHNAK2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP11A | c.2521+8T>A | Splice Region (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- BACH2 | c.157G>C p.A53P | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BAHCC1 | c.2672C>G p.A891G | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CDH23 | c.5430C>A p.D1810E | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CEP78 | c.1931C>A p.S644Y (on ENST00000424347 / NM_001349840.2; = p.S645Y on NM_032171.3) | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- CORO2A | c.202-1G>A p.X68_splice | Splice Site (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- ERICH6 | c.1709G>A p.S570N | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EVI5L | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- HGF | c.810G>T p.W270C | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGKV4-1 | c.170_191del p.N57Rfs*? | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | called by mutect2, pindel, varscan2
- IGLV1-44 | c.314A>C p.D105A | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2
- IGLV4-60 | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 88/217 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, varscan2
- IGLV4-60 | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, varscan2
- ITGB4 | c.3773G>C p.G1258A | Missense Mutation (SNP) | VAF 117/293 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- KALRN | c.1279T>G p.F427V | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- MORC2 | c.2330C>T p.S777L (on ENST00000397641 / NM_001303256.3; = p.S715L on NM_014941.3) | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.081); called by muse, mutect2
- NFKBIZ | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PCLO | c.10465A>G p.R3489G | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM14 | c.1183+2T>C p.X395_splice | Splice Site (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2
- PTPRK | c.794A>C p.Q265P | Missense Mutation (SNP) | VAF 137/328 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RYR2 | c.11966A>C p.N3989T | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC23IP | c.2012_2025del p.D671Afs*6 | Frame Shift Del (DEL) | VAF 74/161 reads (46%) | called by mutect2, pindel, varscan2
- TMEM132B | c.2216C>A p.A739E | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- TMEM237 | c.779A>C p.N260T (on ENST00000409883 / NM_001044385.3; = p.N252T on NM_152388.4) | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TRIM77 | c.515T>G p.I172R | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- USP20 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF865 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 128/372 reads (34%) | SIFT tolerated (0.09); called by muse, mutect2, varscan2
- AHNAK2 | c.1572T>G p.G524= | Silent (SNP) | VAF 69/215 reads (32%) | called by muse, mutect2, varscan2
- AHNAK2 | c.327G>A p.E109= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as rs761650221, COSV100319123; called by muse, mutect2, varscan2
- C12orf43 | c.180G>A p.P60= | Silent (SNP) | VAF 97/248 reads (39%) | catalogued as rs143450063; called by muse, mutect2, varscan2
- CAMK1G | c.1080C>T p.V360= | Silent (SNP) | VAF 132/467 reads (28%) | called by muse, varscan2
- DCHS1 | c.1152C>T p.L384= | Silent (SNP) | VAF 120/310 reads (39%) | catalogued as rs1256894240, COSV55042821; called by muse, mutect2, varscan2
- FAT3 | c.3966C>T p.G1322= | Silent (SNP) | VAF 9/218 reads (4%) | catalogued as rs1481646907; called by muse, mutect2
- GRID2 | c.2694G>A p.S898= | Silent (SNP) | VAF 170/383 reads (44%) | catalogued as rs759890016; called by muse, mutect2, varscan2
- H3C13 | c.393C>T p.I131= | Silent (SNP) | VAF 136/498 reads (27%) | called by muse, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 34/44 reads (77%) | catalogued as rs376111067; called by muse, varscan2
- LRP1B | c.2229A>G p.G743= | Silent (SNP) | VAF 39/125 reads (31%) | called by muse, mutect2, varscan2
- MGA | c.8910G>A p.K2970= (on ENST00000219905 / NM_001164273.1; = p.K2761= on NM_001080541.2) | Silent (SNP) | VAF 45/108 reads (42%) | called by muse, mutect2, varscan2
- MROH2A | c.3936C>T p.D1312= | Silent (SNP) | VAF 52/108 reads (48%) | catalogued as rs965636151; called by muse, mutect2, varscan2
- NRXN3 | c.324G>A p.T108= (on ENST00000557594 / NM_001272020.2; = p.T740= on NM_004796.6) | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as rs200794295; called by muse, mutect2, varscan2
- OR7A10 | c.612G>A p.A204= | Silent (SNP) | VAF 65/341 reads (19%) | catalogued as rs759640189; called by muse, mutect2, varscan2
- PDGFRA | c.3180C>T p.I1060= | Silent (SNP) | VAF 62/144 reads (43%) | called by muse, mutect2, varscan2
- TDRD6 | c.438G>A p.P146= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as rs747536212, COSV60175744; called by muse, mutect2, varscan2
- TPRN | c.1974C>T p.S658= | Silent (SNP) | VAF 145/223 reads (65%) | catalogued as rs1434202083; called by muse, mutect2, varscan2
- AC027612.1 | n.2295C>A | RNA (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- AGBL4 | c.1267+3026T>G | Intron (SNP) | VAF 79/160 reads (49%) | called by muse, mutect2, varscan2
- AKAP13 | c.*4333G>A | 3'UTR (SNP) | VAF 45/144 reads (31%) | catalogued as rs1049253820; called by muse, mutect2, varscan2
- ALDH1L2 | c.*3489G>T | 3'UTR (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2
- ARID1B | c.4856-83_4856-81delinsAGAA | Intron (INS) | VAF 12/26 reads (46%) | called by pindel, varscan2*
- ATXN1 | c.*826del | 3'UTR (DEL) | VAF 86/133 reads (65%) | called by mutect2, varscan2
- BCL7A | chr12:122021335 G>C | 5'Flank (SNP) | VAF 41/138 reads (30%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021469 GCGTCCCGAACCGGTGCCTTC>AA | 5'Flank (DEL) | VAF 102/223 reads (46%) | called by pindel, varscan2*
- BHLHE22 | c.*917G>T | 3'UTR (SNP) | VAF 5/73 reads (7%) | catalogued as COSV58862692; called by muse, mutect2
- CACNA2D1 | c.*110C>A | 3'UTR (SNP) | VAF 51/125 reads (41%) | catalogued as COSV100667500; called by muse, mutect2, varscan2
- CELSR2 | c.8745-97C>T | Intron (SNP) | VAF 96/229 reads (42%) | called by muse, mutect2, varscan2
- CEP78 | c.*433C>T | 3'UTR (SNP) | VAF 14/124 reads (11%) | catalogued as rs576317283; called by muse, mutect2, varscan2
- COL6A2 | c.2461+2524C>A | Intron (SNP) | VAF 65/151 reads (43%) | called by muse, mutect2, varscan2
- DNAH14 | c.1033-4539C>T | Intron (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- DOC2A | c.*423T>G | 3'UTR (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- DPY19L2 | c.*1207C>A | 3'UTR (SNP) | VAF 44/144 reads (31%) | called by muse, mutect2, varscan2
- DPY19L2 | c.*1048T>C | 3'UTR (SNP) | VAF 50/185 reads (27%) | called by muse, mutect2, varscan2
- DYNC1LI2 | c.*874A>C | 3'UTR (SNP) | VAF 41/66 reads (62%) | catalogued as rs922164701; called by muse, mutect2, varscan2
- ELP2 | c.2211-106T>A | Intron (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- FAM183BP | n.227G>A | RNA (SNP) | VAF 19/99 reads (19%) | catalogued as rs761829719; called by muse, mutect2, varscan2
- FOXI2 | c.*1502G>T | 3'UTR (SNP) | VAF 62/114 reads (54%) | called by muse, mutect2, varscan2
- GFOD1 | c.-670G>A | 5'UTR (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- GTF3C4 | c.*4478_*4485del | 3'UTR (DEL) | VAF 37/134 reads (28%) | called by mutect2, pindel, varscan2
- HAUS8 | c.788-57T>C | Intron (SNP) | VAF 17/66 reads (26%) | called by mutect2, varscan2
- HSPA7 | n.1907A>G | RNA (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- IGHD3-10 | c.*1C>G | 3'UTR (SNP) | VAF 21/22 reads (95%) | called by muse, mutect2, varscan2
- JMJD4 | c.*486T>G | 3'UTR (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- KIF5A | c.2993-33C>T | Intron (SNP) | VAF 37/114 reads (32%) | catalogued as rs1259746245; called by muse, mutect2, varscan2
- LPL | c.89-1559C>T | Intron (SNP) | VAF 13/21 reads (62%) | catalogued as rs890125493; called by muse, mutect2, varscan2
- LRP3 | c.*1234C>A | 3'UTR (SNP) | VAF 28/68 reads (41%) | catalogued as rs953110332; called by muse, varscan2
- NTF3 | c.-31del | 5'UTR (DEL) | VAF 78/188 reads (41%) | catalogued as COSV100451106; called by mutect2, pindel, varscan2
- ODF2L | chr1:86349629 G>A | 3'Flank (SNP) | VAF 15/35 reads (43%) | catalogued as rs1272073565; called by muse, mutect2, varscan2
- ODF2L | chr1:86349721 G>C | 3'Flank (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- ODF2L | chr1:86349722 G>A | 3'Flank (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- ODF2L | chr1:86350054 G>C | 3'Flank (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- OR10D1P | n.87T>C | RNA (SNP) | VAF 104/220 reads (47%) | called by muse, mutect2, varscan2
- OR2J3 | c.*3C>T | 3'UTR (SNP) | VAF 73/448 reads (16%) | called by muse, mutect2, varscan2
- PLPPR5 | c.*1440A>C | 3'UTR (SNP) | VAF 9/17 reads (53%) | catalogued as rs1349342176; called by muse, mutect2, varscan2
- PRR18 | c.*1496T>G | 3'UTR (SNP) | VAF 72/155 reads (46%) | called by muse, mutect2, varscan2
- PTPRT | c.*3615C>A | 3'UTR (SNP) | VAF 54/170 reads (32%) | called by muse, mutect2, varscan2
- RBBP8NL | c.*431C>T | 3'UTR (SNP) | VAF 48/113 reads (42%) | catalogued as rs1162086294; called by muse, mutect2, varscan2
- RHEX | c.112+13G>T | Intron (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- RIC8B | chr12:106887457 T>A | 3'Flank (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- RN7SL860P | chr19:22600308 A>C | 5'Flank (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- SCPEP1 | c.658-40C>G | Intron (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- SH3BGRL | c.-41C>A | 5'UTR (SNP) | VAF 60/70 reads (86%) | called by muse, mutect2, varscan2
- SOX11 | c.*7012G>A | 3'UTR (SNP) | VAF 65/146 reads (45%) | catalogued as rs1398682927; called by muse, mutect2, varscan2
- SOX17 | c.*8C>T | 3'UTR (SNP) | VAF 109/263 reads (41%) | called by muse, mutect2, varscan2
- STAU1 | c.206-4418G>C | Intron (SNP) | VAF 71/159 reads (45%) | called by muse, mutect2, varscan2
- TTC6 | c.358-1401C>T | Intron (SNP) | VAF 21/57 reads (37%) | catalogued as rs962068281; called by muse, mutect2, varscan2
- ZDHHC16 | c.*435G>A | 3'UTR (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- ZNF419 | c.*357G>T | 3'UTR (SNP) | VAF 55/182 reads (30%) | called by muse, mutect2, varscan2
- ZNF596 | c.-73+453G>A | Intron (SNP) | VAF 30/60 reads (50%) | catalogued as rs1253586079; called by muse, mutect2, varscan2
